Gene-level copy-number profile of tumor specimen TARGET-40-0A4HY5-01A from TARGET case TARGET-40-0A4HY5, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 19.9 years (7,264 days).
Specimen TARGET-40-0A4HY5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.ff02292f-8eb8-543a-a453-d9e78eaf610e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4HY5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate.
https://portal.gdc.cancer.gov/files/a92881a7-0880-4879-9c49-6315af936491

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,493; copy number 1: 1,898; copy number 2: 30,933; copy number 3: 21,861; copy number 4: 2,292; copy number 5: 813; copy number 6: 831; copy number 7: 60; copy number 8: 24; copy number 9: 13; copy number 10: 3; copy number 23: 3.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:8,717,684–8,717,883, 1 gene: AC091932.4.
- chr11:55,635,113–55,674,675, 4 genes: OR4P4, OR4S2, OR4C6, OR4V1P.
- chr17:7,646,627–7,687,538, 2 genes: ATP1B2, TP53.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,747 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,361,922–41,383,590, 2 genes, copy number 5 (within-gene range 3–5): FOXO6, FOXO6-AS1.
- chr2:145,569,294–145,588,024, 1 gene, copy number 5: AC092484.1.
- chr2:145,600,907–145,603,423, 1 gene, copy number 5: AC079163.1.
- chr2:166,403,573–166,611,482, 1 gene, copy number 5 (within-gene range 2–5): SCN7A.
- chr5:58,198–189,972, 2 genes, copy number 7 (within-gene range 3–7): AC113430.1, PLEKHG4B.
- chr5:23,013,048–28,214,559, 53 genes, copy number 5–6: AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1.
- chr5:57,574,027–57,619,816, 1 gene, copy number 6: LINCR-0003.
- chr7:16,753,755–16,888,885, 6 genes, copy number 5: TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:25,118,656–27,662,883, 88 genes, copy number 6 (broad region; genes not listed).
- chr7:34,209,465–34,299,012, 2 genes, copy number 5 (within-gene range 3–5): AC009262.1, RNU6-438P.
- chr8:41,929,479–46,028,892, 58 genes, copy number 5: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1, AC118650.1.
- chr8:82,862,779–83,408,900, 6 genes, copy number 5 (within-gene range 4–5): AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419.
- chr8:88,032,011–91,907,619, 38 genes, copy number 5–10 (within-gene range 4–10): MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231.
- chr8:111,225,585–121,994,185, 82 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:125,648,327–129,786,624, 54 genes, copy number 5–23 (within-gene range 3–23): AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC.
- chr9:14,475–16,061,663, 212 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr9:30,935,485–34,134,696, 83 genes, copy number 5 (broad region; genes not listed).
- chr9:35,147,410–37,592,604, 91 genes, copy number 5 (broad region; genes not listed).
- chr9:37,636,688–37,637,293, 1 gene, copy number 5: RAB1C.
- chr9:37,661,747–37,662,049, 1 gene, copy number 5: RN7SKP171.
- chr9:38,433,696–38,543,880, 1 gene, copy number 5 (within-gene range 4–5): AL390726.5.
- chr9:38,478,471–41,701,096, 100 genes, copy number 5 (broad region; genes not listed).
- chr16:15,949,138–16,762,465, 25 genes, copy number 5 (within-gene range 2–5): ABCC1, RPL17P40, ABCC6, AC136624.1, NOMO3, AC136624.3, AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, PKD1P2, MIR6511A3, NPIPA7, AC136619.1, AC136431.1, AC136619.2, AC136431.2, AC092326.1.
- chr16:24,400,056–25,088,618, 13 genes, copy number 6 (within-gene range 4–6): RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4.
- chr16:69,762,328–69,941,741, 1 gene, copy number 6 (within-gene range 2–6): WWP2.
- chr18:24,725,762–25,056,760, 4 genes, copy number 5 (within-gene range 4–5): AC018697.1, LINC01894, WBP2P1, AC104961.1.
- chr18:26,170,726–26,657,401, 13 genes, copy number 5: DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P.
- chr18:27,785,821–28,177,946, 4 genes, copy number 5: AC090936.1, CDH2, AC110015.1, AC006249.1.
- chr18:48,475,487–48,479,228, 3 genes, copy number 6: RNA5SP456, AC024288.1, POLR3GP2.
- chr19:7,830,233–9,793,180, 100 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:12,898,786–13,141,147, 19 genes, copy number 8 (within-gene range 3–8): SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1.
- chr20:15,552,157–15,985,876, 3 genes, copy number 6: AL121584.1, ENSAP1, AL079338.1.
- chr21:14,961,235–46,665,124, 678 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,001. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
